Somatic mutation profile of tumor specimen TCGA-D7-A6EZ-01A (aliquot TCGA-D7-A6EZ-01A-11D-A31L-08) from TCGA case TCGA-D7-A6EZ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.9 years (24,425 days).
Specimen TCGA-D7-A6EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a8d5e5d-48ef-419c-92b8-b4d458e5d61b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6EZ-10A (Blood Derived Normal), aliquot TCGA-D7-A6EZ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/867bbb6a-0677-464d-82ba-0f72799e54c3

The open-access MAF lists 293 somatic variants for this specimen: 241 protein-altering or splice-affecting, 47 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 47, Frame Shift Del 16, Nonsense Mutation 14, In Frame Del 8, Splice Site 6, Intron 3, Splice Region 2, 3'UTR 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 38/53 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4500G>T p.E1500D | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99288145; called by muse, mutect2, varscan2
- ABCA12 | c.5797G>A p.G1933S (on ENST00000272895 / NM_173076.3; = p.G1615S on NM_015657.3) | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99788963; called by muse, mutect2, varscan2
- ABCB6 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 158/513 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs532805022, COSV99202382; called by muse, mutect2, varscan2
- ABCE1 | c.689T>G p.V230G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99668468; called by muse, mutect2, varscan2
- ACAP2 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100461685; called by muse, mutect2, varscan2
- ACOT11 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100156783; called by muse, mutect2, varscan2
- ADAM19 | c.1545C>A p.N515K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99976520; called by muse, mutect2, varscan2
- ADAMTS12 | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs780506138, COSV61255039, COSV61262098; called by muse, mutect2, varscan2
- ADAMTS5 | c.1034A>C p.Q345P | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99537234; called by muse, mutect2, varscan2
- ADGRB1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100029371; called by muse, mutect2, varscan2
- AFF3 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1395097402, COSV57855428; called by muse, mutect2, varscan2
- AGK | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV100814513; called by muse, mutect2, varscan2
- AHDC1 | c.3349C>G p.L1117V | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99899030, COSV99899649; called by muse, mutect2, varscan2
- AIFM3 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.091); catalogued as COSV99301450; called by muse, mutect2
- AKAP13 | c.3680C>G p.T1227S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.038); catalogued as COSV100773320; called by muse, mutect2, varscan2
- AKR7A3 | c.278T>C p.F93S | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100853797; called by muse, mutect2
- ALCAM | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.239); catalogued as COSV60257231; called by muse, mutect2, varscan2
- AMFR | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as rs1222595563, COSV99315716; called by muse, mutect2, varscan2
- AMOTL2 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781488712, COSV51438704; called by muse, mutect2, varscan2
- ANP32D | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99874241; called by muse, mutect2, varscan2
- ARHGAP5 | c.1443A>C p.E481D | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV100565112; called by muse, mutect2, varscan2
- ARID1A | c.3947C>A p.S1316* | Nonsense Mutation (SNP) | VAF 94/148 reads (64%) | catalogued as COSV100250732; called by muse, mutect2, varscan2
- ARPP21 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99491404; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2075A>G p.H692R | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.159); catalogued as rs1268922237, COSV99230645; called by muse, mutect2, varscan2
- B3GNT4 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs972389008, COSV99928087, COSV99928322; called by muse, mutect2, varscan2
- BRCA2 | c.9141G>C p.Q3047H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1358886039, COSV101204020; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as COSV55571959, COSV99836267; called by muse, mutect2, varscan2
- C9orf152 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV68762956; called by muse, mutect2, varscan2
- CACNA2D1 | c.937A>G p.R313G | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100666125; called by muse, mutect2, varscan2
- CARS1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV99542250; called by muse, mutect2, varscan2
- CCP110 | c.2365C>G p.Q789E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV66818198; called by muse, mutect2, varscan2
- CCR5 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs764278401, CM104770, COSV52751490; called by muse, mutect2, varscan2
- CCR9 | c.895T>G p.F299V (on ENST00000357632 / NM_031200.3; = p.F287V on NM_006641.4) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV100591626; called by muse, mutect2, varscan2
- CD300LB | c.444-2A>T p.X148_splice | Splice Site (SNP) | VAF 34/71 reads (48%) | catalogued as COSV100075352; called by muse, mutect2, varscan2
- CDK14 | c.1046T>C p.L349P (on ENST00000380050 / NM_001287135.2; = p.L331P on NM_012395.3) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99724224; called by muse, mutect2, varscan2
- CEP85 | c.1715G>A p.W572* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99431943; called by muse, mutect2, varscan2
- CHDH | c.1784A>T p.*595Lext*13 | Nonstop Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55441146, COSV99857156; called by muse, mutect2, varscan2
- CHRNA2 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.174); catalogued as COSV99532022; called by muse, mutect2, varscan2
- CHRNG | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV101263904; called by muse, mutect2, varscan2
- CNNM1 | c.2526C>A p.C842* | Nonsense Mutation (SNP) | VAF 47/90 reads (52%) | catalogued as COSV100763793; called by muse, mutect2, varscan2
- COL12A1 | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59389044; called by muse, mutect2, varscan2
- COL17A1 | c.4430G>T p.G1477V | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100211592, COSV100212038; called by muse, mutect2, varscan2
- COL18A1 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.221); catalogued as COSV100700540; called by muse, mutect2, varscan2
- COL18A1 | c.5233A>G p.I1745V (on ENST00000359759 / NM_130444.3; = p.I1510V on NM_030582.4) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100229184; called by muse, mutect2, varscan2
- COPA | c.2244C>G p.I748M | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.855); catalogued as COSV99614971; called by muse, mutect2, varscan2
- CPNE8 | c.405A>T p.I135= | Splice Region (SNP) | VAF 71/225 reads (32%) | catalogued as COSV100504097; called by muse, mutect2, varscan2
- CRCT1 | c.141C>G p.C47W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | PolyPhen probably damaging (0.91); catalogued as COSV100524189, COSV57500251; called by muse, mutect2, varscan2
- CRLF3 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100158322; called by muse, mutect2, varscan2
- CROT | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519424, COSV100519678; called by muse, mutect2, varscan2
- CTNNAL1 | c.1564A>G p.I522V | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.987); catalogued as COSV100336407; called by muse, mutect2, varscan2
- CUL7 | c.1337A>T p.Y446F | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.035); catalogued as COSV99538130; called by muse, mutect2, varscan2
- DDX58 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV101152617; called by muse, mutect2, varscan2
- DEFB123 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV66232921; called by muse, mutect2, varscan2
- DENND5A | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100064278; called by muse, mutect2, varscan2
- DHX9 | c.1778A>G p.K593R | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100841291, COSV62362882, COSV62362885; called by muse, mutect2, varscan2
- DISP1 | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52657133, COSV99450360; called by muse, mutect2, varscan2
- DNAH10 | c.2812C>G p.L938V (on ENST00000409039; = p.L877V on NM_207437.3) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV101292102; called by muse, mutect2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- DNAJC13 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.977); catalogued as COSV99606888; called by muse, mutect2, varscan2
- ECD | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as COSV100881385, COSV65898705; called by muse, mutect2, varscan2
- EML3 | c.1037C>G p.T346R | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV53881942, COSV99605813; called by muse, mutect2, varscan2
- EP400 | c.5635C>T p.R1879C | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304238186, COSV57782760; called by muse, mutect2, varscan2
- EPB41L3 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as rs1022415466, COSV100548374; called by muse, mutect2, varscan2
- EPX | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99836341; called by muse, mutect2, varscan2
- EXTL1 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100959075; called by muse, mutect2, varscan2
- FANCA | c.3830G>C p.S1277T | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV99234686; called by muse, mutect2, varscan2
- FAT3 | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.953); catalogued as rs776104026, COSV99963381; called by muse, mutect2, varscan2
- FGF21 | c.251A>T p.K84I | Missense Mutation (SNP) | VAF 127/331 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV55811275, COSV99711404; called by muse, mutect2, varscan2
- FH | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844991; called by muse, mutect2, varscan2
- FYB1 | c.775T>G p.F259V | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278361003, COSV100685069; called by muse, mutect2, varscan2
- GABRD | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs749733672, COSV66080438; called by muse, varscan2
- GBE1 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101450116; called by muse, mutect2, varscan2
- GCC2 | c.4169T>A p.L1390Q | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100565326; called by muse, mutect2
- GCK | c.751A>C p.M251L | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as CM030443, COSV100357087; called by muse, mutect2, varscan2
- GCN1 | c.6364G>T p.E2122* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100324820; called by muse, mutect2, varscan2
- GEMIN5 | c.1379+2T>A p.X460_splice | Splice Site (SNP) | VAF 112/321 reads (35%) | catalogued as COSV99593742; called by muse, mutect2, varscan2
- GLG1 | c.2947G>C p.D983H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV99215478; called by muse, mutect2, varscan2
- GLI3 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.513); catalogued as rs1166711228, COSV67887103; called by muse, mutect2, varscan2
- GRHL3 | c.1224G>A p.M408I (on ENST00000350501 / NM_198174.3; = p.M413I on NM_021180.3) | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as COSV99359151; called by muse, mutect2
- GRHL3 | c.1225C>A p.R409S (on ENST00000350501 / NM_198174.3; = p.R414S on NM_021180.3) | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52565202, COSV99359152; called by muse, mutect2
- GRIK2 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV100024225; called by muse, mutect2, varscan2
- GRM2 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV99622558; called by muse, mutect2, varscan2
- GSDME | c.401A>C p.E134A | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV100742278; called by muse, mutect2, varscan2
- GZMH | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.16); catalogued as rs766652570, COSV53537686; called by muse, mutect2, varscan2
- HEATR5B | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV99248686; called by muse, mutect2, varscan2
- HECW1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 69/165 reads (42%) | catalogued as COSV101223039, COSV67839296; called by muse, mutect2, varscan2
- HEPHL1 | c.698T>A p.V233E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100243681; called by muse, mutect2, varscan2
- HJV | c.1016C>G p.T339S (on ENST00000336751 / NM_213653.4; = p.T226S on NM_145277.5) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100382225; called by muse, mutect2, varscan2
- HLA-C | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100880185; called by muse, mutect2, varscan2
- HPS5 | c.2720C>T p.S907L (on ENST00000349215 / NM_181507.2; = p.S793L on NM_007216.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100752252; called by muse, mutect2, varscan2
- HSP90AB1 | c.1886A>T p.N629I | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240989; called by muse, mutect2, varscan2
- ICAM5 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99703202; called by muse, mutect2, varscan2
- IL2RB | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV99344775; called by muse, mutect2, varscan2
- IL4 | c.135+1G>T p.X45_splice | Splice Site (SNP) | VAF 40/145 reads (28%) | catalogued as COSV99184991; called by muse, mutect2, varscan2
- INSR | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs146490822; called by muse, mutect2, varscan2
- INSRR | c.2721C>G p.F907L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV100947275; called by muse, mutect2, varscan2
- ITGAV | c.2177G>C p.G726A | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99654473; called by muse, mutect2, varscan2
- JADE2 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 118/306 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1424572219, COSV99252891; called by muse, mutect2, varscan2
- KCND2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100474422; called by muse, mutect2, varscan2
- KCNG1 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100857020; called by muse, mutect2, varscan2
- KCNK3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1163692084, COSV100256710; called by muse, mutect2, varscan2
- KCNMB3 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100566639; called by muse, mutect2, varscan2
- KIF22 | c.1817G>T p.S606I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99360940; called by muse, mutect2, varscan2
- KRT6B | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1306241693, COSV52885425, COSV99360546; called by muse, mutect2, varscan2
- LAGE3 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 90/119 reads (76%) | SIFT tolerated (0.46); PolyPhen benign (0.182); catalogued as COSV100635689, COSV62074175; called by muse, mutect2, varscan2
- LHCGR | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99683349; called by muse, mutect2, varscan2
- LHFPL3 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.506); catalogued as COSV101308282, COSV67818340; called by muse, mutect2, varscan2
- LIFR | c.3068A>G p.D1023G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99663624; called by muse, mutect2, varscan2
- LRRN3 | c.1741A>T p.T581S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV100068853; called by muse, mutect2, varscan2
- MAP2 | c.5012A>C p.K1671T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52285419, COSV99557516; called by muse, mutect2, varscan2
- MAST2 | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100787946; called by muse, varscan2
- MCM8 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138393496; called by muse, mutect2, varscan2
- MCMDC2 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142450719; called by muse, mutect2, varscan2
- MED17 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.961); catalogued as COSV99315805; called by muse, mutect2, varscan2
- MFSD8 | c.317C>G p.P106R | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614237; called by muse, mutect2, varscan2
- MFSD9 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301979; called by muse, mutect2
- MICAL2 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99816925; called by muse, mutect2, varscan2
- MINDY4 | c.2022T>A p.S674R | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518357; called by muse, mutect2, varscan2
- MKI67 | c.9479G>C p.R3160T | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.53); catalogued as COSV100896325; called by muse, mutect2, varscan2
- MRAS | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV100003616; called by muse, mutect2, varscan2
- MROH7 | c.3849G>C p.W1283C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100988544, COSV64887705; called by muse, mutect2, varscan2
- MSANTD1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs757753092, COSV101433579; called by muse, mutect2, varscan2
- MYO10 | c.4346C>T p.S1449F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99944934; called by muse, mutect2, varscan2
- MYO15A | c.813G>C p.W271C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV52765630; called by muse, mutect2, varscan2
- NCAN | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as COSV53053841, COSV99386801; called by muse, mutect2, varscan2
- NCDN | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs758633602, COSV100621931; called by muse, mutect2, varscan2
- NDOR1 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs574860139, COSV100641601; called by muse, mutect2, varscan2
- NDST1 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99938710; called by muse, mutect2, varscan2
- NEO1 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99981192; called by muse, mutect2, varscan2
- NETO2 | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100292379; called by muse, mutect2, varscan2
- NOBOX | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99779279; called by muse, mutect2, varscan2
- NPNT | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV99974847; called by muse, mutect2, varscan2
- NPPB | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750160819, COSV100916075; called by muse, mutect2, varscan2
- NRG2 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1036429644, COSV99179986; called by muse, mutect2, varscan2
- NTNG2 | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100647235, COSV100647338; called by muse, mutect2, varscan2
- OBSCN | c.11051G>A p.R3684H | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.086); catalogued as rs571833899, COSV52800150; called by muse, mutect2, varscan2
- OPLAH | c.1245C>G p.N415K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV101470741, COSV70676917; called by muse, mutect2, varscan2
- OR14K1 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99315029; called by muse, mutect2, varscan2
- OR1B1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100506427; called by muse, mutect2, varscan2
- OR2Z1 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100136368; called by muse, mutect2, varscan2
- OR56A1 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100360414; called by muse, mutect2, varscan2
- OR5H14 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs772736386, COSV71194251; called by muse, mutect2
- OVCH1 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100548334; called by muse, mutect2, varscan2
- OXER1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs756470893, COSV54312494; called by muse, mutect2, varscan2
- P2RX5 | c.678C>G p.N226K | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV99835691; called by muse, mutect2, varscan2
- PABPN1 | c.534+2T>C p.X178_splice | Splice Site (SNP) | VAF 51/140 reads (36%) | catalogued as rs768428878, COSV99391118; called by muse, mutect2, varscan2
- PARP10 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1244440291, COSV100477840; called by muse, mutect2, varscan2
- PARP2 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as COSV99162155; called by muse, mutect2, varscan2
- PCDH12 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as COSV99186453; called by muse, mutect2, varscan2
- PCDH18 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100787125; called by muse, mutect2, varscan2
- PELP1 | c.2969A>T p.E990V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs1277702542, COSV99342642; called by muse, mutect2, varscan2
- PI16 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 64/216 reads (30%) | catalogued as COSV101028631, COSV65448206; called by muse, mutect2, varscan2
- PIK3CA | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55992774; called by muse, mutect2, varscan2
- PKD2 | c.690T>A p.F230L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99417051; called by muse, mutect2, varscan2
- PLAG1 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV100387766; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1108G>T p.V370L (on ENST00000611850; = p.V371L on NM_005396.5) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100077667; called by muse, mutect2, varscan2
- PPARGC1B | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 56/159 reads (35%) | catalogued as COSV100494574; called by muse, mutect2, varscan2
- PRRC2A | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100784548; called by muse, mutect2, varscan2
- PSMG1 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100521873; called by muse, mutect2, varscan2
- PTCHD3 | c.2218T>C p.S740P | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV101438876; called by muse, mutect2, varscan2
- PTPRM | c.2718C>T p.S906= | Splice Region (SNP) | VAF 20/41 reads (49%) | catalogued as rs753346418, COSV100155871; called by muse, mutect2, varscan2
- PTX4 | c.883C>T p.R295* (on ENST00000447419 / NM_001328608.2; = p.R290* on NM_001013658.1) | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as rs757126891, COSV53518953; called by muse, mutect2
- RABGGTB | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100174972; called by muse, mutect2, varscan2
- RANBP6 | c.3059C>T p.T1020I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV99424039; called by muse, mutect2, varscan2
- RASAL1 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99921537; called by muse, mutect2, varscan2
- RC3H2 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); catalogued as COSV100106394; called by muse, mutect2, varscan2
- RFX2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs767084173, COSV57942463; called by muse, mutect2, varscan2
- RGS9 | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99287227; called by muse, mutect2, varscan2
- RIMS1 | c.4112G>A p.R1371H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs62407506; called by muse, mutect2, varscan2
- ROBO3 | c.3239A>G p.N1080S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs758160381, COSV101184963; called by muse, mutect2, varscan2
- ROR2 | c.1664A>G p.Y555C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767004305, COSV100995618; called by muse, mutect2, varscan2
- RPGRIP1L | c.2629A>T p.I877L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100046006; called by muse, mutect2, varscan2
- RTN1 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99954972; called by muse, mutect2, varscan2
- SCG5 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 94/231 reads (41%) | catalogued as rs764436055, COSV100276716; called by muse, mutect2, varscan2
- SDK1 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs767644305, COSV101268841; called by muse, mutect2, varscan2
- SEMA6B | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768507422, COSV100014717, COSV56705090; called by muse, mutect2, varscan2
- SERPINA11 | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100593969, COSV100594171; called by muse, mutect2, varscan2
- SFMBT2 | c.2559A>C p.Q853H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100738626, COSV62812352; called by muse, mutect2, varscan2
- SGPP1 | c.562T>G p.S188A | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99905748; called by muse, mutect2, varscan2
- SLC17A4 | c.136T>A p.C46S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as COSV100930529; called by muse, mutect2, varscan2
- SLC17A4 | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV100930530; called by muse, mutect2, varscan2
- SLC4A4 | c.3147G>A p.M1049I (on ENST00000264485 / NM_001098484.3; = p.M1005I on NM_003759.4) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as COSV99139325; called by muse, mutect2, varscan2
- SLC8A1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60479849; called by muse, mutect2, varscan2
- SPAM1 | c.614A>T p.K205I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56142925; called by muse, mutect2, varscan2
- SPTAN1 | c.5440G>C p.A1814P | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs777267488, COSV100823350; called by muse, mutect2, varscan2
- SSMEM1 | c.135T>A p.Y45* | Nonsense Mutation (SNP) | VAF 47/141 reads (33%) | catalogued as COSV99927636; called by muse, mutect2, varscan2
- STAC3 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as rs764988214, COSV100234524; called by muse, mutect2, varscan2
- STYK1 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99311700; called by muse, mutect2, varscan2
- TAS1R2 | c.254A>C p.D85A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV100946164; called by muse, mutect2, varscan2
- TCFL5 | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200910523, COSV99415645; called by muse, mutect2, varscan2
- TERB2 | c.10G>C p.G4R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV100546537; called by muse, mutect2, varscan2
- TET1 | c.1749G>T p.L583F | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101017791, COSV65385001; called by muse, mutect2, varscan2
- TEX2 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366893; called by muse, mutect2, varscan2
- TIGD4 | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100427912; called by muse, mutect2, varscan2
- TNIK | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs929026771, COSV52700380; called by muse, mutect2, varscan2
- TSSK4 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV99841666; called by muse, mutect2, varscan2
- TTC21A | c.2758C>G p.P920A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100087120; called by muse, mutect2, varscan2
- TTC39C | c.1261A>G p.K421E (on ENST00000317571 / NM_001135993.2; = p.K360E on NM_153211.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100455259; called by muse, mutect2, varscan2
- TTC7A | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs199788952, COSV99766180; called by muse, mutect2, varscan2
- TUBAL3 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100990490; called by muse, mutect2, varscan2
- USP24 | c.3083A>T p.Q1028L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV99599146; called by muse, mutect2, varscan2
- USP24 | c.3082C>A p.Q1028K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV99599150; called by muse, mutect2, varscan2
- VEPH1 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV100747443; called by muse, mutect2, varscan2
- VPS13C | c.2623G>C p.D875H (on ENST00000644861 / NM_020821.3; = p.D832H on NM_017684.5) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV99827683; called by muse, mutect2, varscan2
- WDR33 | c.3473-2A>T p.X1158_splice | Splice Site (SNP) | VAF 48/139 reads (35%) | catalogued as COSV100459728; called by muse, mutect2, varscan2
- XIRP2 | c.10016C>G p.S3339C (on ENST00000628543; = p.S3514C on NM_152381.6) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54690736; called by muse, mutect2, varscan2
- XRCC3 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs768891111, COSV100572503; called by muse, mutect2, varscan2
- ZFHX4 | c.5603C>T p.P1868L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs1404045124, COSV99259350; called by muse, mutect2, varscan2
- ZNF585A | c.1103A>T p.E368V (on ENST00000292841 / NM_001288800.2; = p.E313V on NM_152655.3) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV99492866; called by muse, mutect2, varscan2
- ZNF624 | c.1527C>G p.F509L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV100257118; called by muse, mutect2, varscan2
- ZNF675 | c.964A>C p.T322P | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV100704964; called by muse, mutect2, varscan2
- ZNF676 | c.1228T>C p.S410P (on ENST00000650058; = p.S378P on NM_001001411.3) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101236127, COSV68095195; called by muse, mutect2, varscan2
- A3GALT2 | c.198_211del p.W66Cfs*27 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- AC242842.3 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by mutect2, varscan2
- ADCY5 | c.189del p.Q64Sfs*20 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- ARFGEF1 | c.3936_3942del p.H1312Qfs*11 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- CASC3 | c.1593_1598del p.E532_P533del | In Frame Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel
- CDKN1B | c.361del p.A121Lfs*24 | Frame Shift Del (DEL) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- DISP3 | c.1704_1715del p.S569_T572del | In Frame Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel
- ELANE | c.581_588del p.Q194Rfs*93 | Frame Shift Del (DEL) | VAF 21/117 reads (18%) | called by mutect2, varscan2
- EVC2 | c.2557C>G p.Q853E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FOXM1 | c.2059_2081del p.V687Lfs*35 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | called by mutect2, pindel
- GNAT1 | c.373_384del p.R125_K128del | In Frame Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- GNGT2 | c.106_113del p.I36Vfs*17 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.7303_7322del p.V2435Yfs*23 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | called by mutect2, pindel
- HERC2 | c.13058_13089del p.L4353Hfs*87 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel
- HLA-B | c.860_877del p.H287_K292del | In Frame Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel
- LRP6 | c.4838_4842del p.S1613Wfs*15 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel*
- LYZL6 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYO5C | c.1420_1422del p.E474del | In Frame Del (DEL) | VAF 13/42 reads (31%) | called by pindel, varscan2
- MYO7A | c.3503+2_3503+11del p.X1168_splice | Splice Site (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- NCOR1 | c.2666_2671del p.V889_D890del | In Frame Del (DEL) | VAF 31/136 reads (23%) | called by mutect2, pindel, varscan2
- PLEC | c.6947_6958del p.R2316_A2319del (on ENST00000322810 / NM_201380.4; = p.R2206_A2209del on NM_000445.5) | In Frame Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.1149_1165del p.V384Qfs*10 | Frame Shift Del (DEL) | VAF 33/293 reads (11%) | called by mutect2, pindel
- TMEM138 | c.145_160del p.V49Sfs*31 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- TMEM44 | c.265_289del p.V89Lfs*4 | Frame Shift Del (DEL) | VAF 37/183 reads (20%) | called by mutect2, pindel
- TMEM94 | c.1649_1659del p.D550Gfs*18 | Frame Shift Del (DEL) | VAF 39/143 reads (27%) | called by mutect2, pindel, varscan2
- TRAF7 | c.1669_1682del p.T557Rfs*26 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- TRERF1 | c.1929del p.E643Dfs*72 | Frame Shift Del (DEL) | VAF 49/194 reads (25%) | called by mutect2, pindel, varscan2
- TUBA4A | c.776_787del p.L259_Y262del | In Frame Del (DEL) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- ACOT1 | c.696C>G p.S232= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100233391; called by muse, mutect2, varscan2
- ADORA3 | c.700C>T p.L234= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV99598655; called by muse, mutect2, varscan2
- AKR7A3 | c.276G>A p.R92= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as rs766699847, COSV100853798; called by muse, mutect2
- AMBRA1 | c.75T>G p.A25= | Silent (SNP) | VAF 174/508 reads (34%) | catalogued as COSV100093160; called by muse, mutect2, varscan2
- APC | c.2823A>G p.E941= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99966186; called by muse, mutect2, varscan2
- BMPER | c.264C>G p.S88= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV99779193; called by muse, mutect2, varscan2
- BTG4 | c.567T>C p.N189= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV100604407; called by muse, mutect2, varscan2
- CADPS2 | c.3888C>A p.G1296= | Silent (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- CARMIL3 | c.3609G>A p.K1203= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs768103451, COSV99393217; called by muse, mutect2, varscan2
- COL7A1 | c.8202C>T p.G2734= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs200292228, COSV99866164; ClinVar: likely benign; called by muse, mutect2
- DQX1 | c.2145C>A p.V715= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV52045977, COSV99283565; called by muse, mutect2, varscan2
- EPX | c.219G>C p.L73= | Silent (SNP) | VAF 75/300 reads (25%) | catalogued as COSV99836340; called by muse, mutect2, varscan2
- ESYT3 | c.2212C>T p.L738= | Silent (SNP) | VAF 137/295 reads (46%) | catalogued as COSV101272637; called by muse, mutect2, varscan2
- FAM9A | c.69C>T p.A23= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV101121320; called by muse, mutect2, varscan2
- FAT4 | c.13281C>T p.V4427= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV58710215; called by muse, mutect2, varscan2
- FCSK | c.2394G>A p.A798= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs370430240, COSV99850983; called by muse, mutect2, varscan2
- FLNA | c.2289G>C p.V763= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as COSV100774424; called by muse, mutect2, varscan2
- GBE1 | c.267A>G p.K89= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV101450117; called by muse, mutect2, varscan2
- GTF2I | c.360C>T p.F120= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV60399839; called by muse, mutect2, varscan2
- GTF3C4 | c.1533A>G p.Q511= | Silent (SNP) | VAF 57/220 reads (26%) | catalogued as rs745719898, COSV100935953; called by muse, mutect2, varscan2
- INO80D | c.828C>T p.D276= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV101305803; called by muse, mutect2, varscan2
- INS-IGF2 | c.45C>A p.A15= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV99171123; called by muse, mutect2, varscan2
- KIRREL2 | c.1872C>T p.F624= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV52880217; called by muse, mutect2, varscan2
- LDB1 | c.675G>A p.Q225= (on ENST00000425280 / NM_001321612.2; = p.Q189= on NM_003893.5) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100756350; called by muse, mutect2, varscan2
- MKRN3 | c.1323C>T p.Y441= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV100090917; called by muse, mutect2, varscan2
- MTARC1 | c.531C>G p.P177= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs956288180, COSV100856257; called by muse, mutect2, varscan2
- MUC16 | c.12141T>C p.P4047= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as COSV101198816; called by muse, mutect2, varscan2
- MYBPC3 | c.3612C>T p.V1204= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV99920044; called by muse, mutect2, varscan2
- NEURL2 | c.423C>G p.L141= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as COSV51945490; called by muse, mutect2, varscan2
- NLRP3 | c.1317G>A p.A439= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs201976178, COSV60222411, COSV60232179; ClinVar: likely benign; called by muse, mutect2
- NPAS1 | c.852G>A p.V284= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as rs772166889, COSV101463926; called by muse, mutect2, varscan2
- PCDHGA12 | c.1506G>A p.S502= | Silent (SNP) | VAF 49/145 reads (34%) | catalogued as rs756993242, COSV99338811; called by muse, mutect2, varscan2
- PDE1C | c.237A>G p.E79= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100371656; called by muse, mutect2
- PMPCA | c.21G>C p.A7= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100048067; called by muse, mutect2, varscan2
- PRDM9 | c.9T>C p.P3= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99690029; called by muse, mutect2, varscan2
- PRSS3 | c.165T>G p.A55= (on ENST00000361005 / NM_007343.4; = p.A163= on NM_002771.3) | Silent (SNP) | VAF 77/193 reads (40%) | catalogued as COSV100725194; called by muse, varscan2
- RTN3 | c.2883T>C p.A961= (on ENST00000377819 / NM_001265589.2; = p.A165= on NM_006054.4) | Silent (SNP) | VAF 95/322 reads (30%) | catalogued as COSV100379978; called by muse, mutect2, varscan2
- SEC61A1 | c.1077C>G p.V359= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as COSV99684759; called by muse, mutect2, varscan2
- SOX2 | c.171C>A p.R57= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV100327129; called by muse, mutect2, varscan2
- SPINK4 | c.84G>A p.S28= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs745978913, COSV101121895, COSV101121898; called by muse, mutect2, varscan2
- TERT | c.1692G>A p.T564= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs377217777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIO | c.7548C>T p.H2516= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1561550051, COSV100702482; called by muse, mutect2, varscan2
- TRPM8 | c.819C>T p.V273= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs200501002; called by muse, mutect2, varscan2
- TTC21B | c.3021A>G p.R1007= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs370767165; called by muse, mutect2, varscan2
- WDR90 | c.4665C>T p.C1555= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV99552919; called by muse, mutect2, varscan2
- XIRP2 | c.1971A>G p.K657= (on ENST00000628543; = p.K832= on NM_152381.6) | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as COSV99740147; called by muse, mutect2, varscan2
- XPO1 | c.1710C>T p.F570= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs150009195; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502978 G>A | 5'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as rs529425393; called by muse, varscan2
- ASPSCR1 | c.1354-1191C>T | Intron (SNP) | VAF 58/142 reads (41%) | catalogued as COSV100142364; called by muse, mutect2, varscan2
- C15orf65 | c.19-113A>C | Intron (SNP) | VAF 11/26 reads (42%) | catalogued as COSV101041162; called by muse, mutect2, varscan2
- GAD1 | c.*2C>T | 3'UTR (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100827910; called by muse, mutect2, varscan2
- NCF4 | c.758+114C>G | Intron (SNP) | VAF 46/122 reads (38%) | catalogued as COSV99957201; called by muse, mutect2, varscan2
